Somatic mutation profile of tumor specimen 0DPDI4 from CCDI case PBCBDE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,116 days).
Specimen 0DPDI4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9cfb9a54-4973-4351-8674-9dbd335c0d79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPDH9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51e551f9-05ff-4efa-825b-32eb4f658601

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN2A1 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 58/822 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs149413459; called by muse, mutect2
- PEG3 | c.2761G>A p.E921K | Missense Mutation (SNP) | VAF 35/458 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as rs752285045, COSV55629456; called by muse, mutect2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 34/1110 reads (3%) | called by muse, mutect2
- UVSSA | c.*9559C>T | 3'UTR (SNP) | VAF 139/402 reads (35%) | catalogued as rs777616074, COSV61347185; called by muse, mutect2, varscan2
